ALCHEMIST case ALCH-B2MP — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/997d93c5-b7b2-4987-90de-43c011992db8

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 63.1 years (23,046 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2MP-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2MP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2MP-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 39; Percent tumor nuclei: 36; Percent normal cells: 45; Percent necrosis: 2; Percent stromal cells: 14; Percent lymphocyte infiltration: 59; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 4.
